Somatic mutation profile of tumor specimen TCGA-HZ-A8P1-01A (aliquot TCGA-HZ-A8P1-01A-11D-A377-08) from TCGA case TCGA-HZ-A8P1, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Tail of pancreas; AJCC pathologic stage: Stage IB; Tumor grade: G1; Age at diagnosis: 81.1 years (29,631 days).
Specimen TCGA-HZ-A8P1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d0b0e77a-7514-49eb-a703-2a45b06a87fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HZ-A8P1-10A (Blood Derived Normal), aliquot TCGA-HZ-A8P1-10A-01D-A37A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99fe9e3b-eab3-4446-83ad-96c7e5596914

The open-access MAF lists 64 somatic variants for this specimen: 42 protein-altering or splice-affecting, 22 silent.
By variant classification: Missense Mutation 32, Silent 22, Frame Shift Del 4, Splice Site 2, Nonsense Mutation 2, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KCNQ1 | c.1265del p.K422Sfs*10 | Frame Shift Del (DEL) | VAF 96/360 reads (27%) | catalogued as rs397508083; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 83/289 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACADM | c.1108A>G p.T370A | Missense Mutation (SNP) | VAF 131/306 reads (43%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV100897697; called by muse, mutect2, varscan2
- ASIC1 | c.250C>G p.Q84E | Missense Mutation (SNP) | VAF 67/281 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99948114; called by muse, mutect2, varscan2
- BTRC | c.261C>G p.C87W (on ENST00000370187 / NM_033637.4; = p.C51W on NM_003939.5) | Missense Mutation (SNP) | VAF 100/305 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV100926568; called by muse, mutect2, varscan2
- CDHR1 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 35/144 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258981, COSV60562804; called by muse, mutect2, varscan2
- CORO1B | c.385G>C p.E129Q | Missense Mutation (SNP) | VAF 49/227 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.177); catalogued as rs1212699930, COSV100396576; called by muse, mutect2, varscan2
- DEF8 | c.710G>T p.R237L | Missense Mutation (SNP) | VAF 179/591 reads (30%) | SIFT tolerated (0.77); PolyPhen possibly damaging (0.796); catalogued as COSV99240556; called by muse, mutect2, varscan2
- ECD | c.805T>C p.Y269H | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100881443; called by muse, mutect2, varscan2
- EYS | c.1459+2T>A p.X487_splice | Splice Site (SNP) | VAF 100/260 reads (38%) | catalogued as COSV60982378; called by muse, mutect2, varscan2
- GABRG3 | c.1336C>T p.R446W | Missense Mutation (SNP) | VAF 40/168 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1347328325, COSV100407014, COSV100407878; called by muse, mutect2, varscan2
- HDAC9 | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 43/367 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs763335887, COSV67773992; called by muse, mutect2, varscan2
- IFT46 | c.818A>G p.Q273R (on ENST00000264021 / NM_001168618.2; = p.Q324R on NM_020153.3) | Missense Mutation (SNP) | VAF 189/562 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV99871072; called by muse, mutect2, varscan2
- IKBKB | c.45G>A p.W15* | Nonsense Mutation (SNP) | VAF 121/267 reads (45%) | catalogued as COSV100645734; called by muse, mutect2, varscan2
- IKBKB | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 121/265 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV60596429; called by muse, mutect2, varscan2
- INTS13 | c.675G>C p.E225D | Missense Mutation (SNP) | VAF 61/232 reads (26%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as COSV99677420, COSV99677526; called by muse, mutect2, varscan2
- INTS14 | c.722A>G p.D241G (on ENST00000313182 / NM_001366360.2; = p.D162G on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 88/300 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100499977; called by muse, mutect2, varscan2
- KIAA1210 | c.4047G>T p.K1349N | Missense Mutation (SNP) | VAF 85/733 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as COSV101274244; called by muse, mutect2, varscan2
- KRTAP24-1 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 155/490 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.019); catalogued as rs200135144, COSV61089693; called by muse, mutect2, varscan2
- MCF2L | c.2705C>T p.T902M (on ENST00000375608; = p.T870M on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770639443, COSV56182559; called by muse, mutect2, varscan2
- METAP1 | c.1151C>T p.S384F | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV99595693; called by muse, mutect2, varscan2
- MYOM2 | c.4175C>T p.S1392L | Missense Mutation (SNP) | VAF 110/218 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs367862562; called by muse, mutect2, varscan2
- NAIP | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 181/554 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.01); catalogued as COSV99519320; called by muse, mutect2, varscan2
- NPY1R | c.839C>T p.T280I | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.317); catalogued as COSV56715714; called by muse, mutect2, varscan2
- OR5M8 | c.58C>T p.R20W | Missense Mutation (SNP) | VAF 129/421 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs765367044, COSV100510695; called by muse, mutect2, varscan2
- OTOGL | c.5478C>A p.N1826K (on ENST00000547103; = p.N1817K on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1288573890, COSV100087388; called by muse, mutect2, varscan2
- PBRM1 | c.1619G>C p.R540T | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56301116, COSV56301478; called by muse, mutect2
- PKD2 | c.2225G>A p.R742Q | Missense Mutation (SNP) | VAF 83/307 reads (27%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.963); catalogued as rs1005107425, COSV52938282; called by muse, mutect2, varscan2
- SLC10A6 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV99907295; called by muse, mutect2, varscan2
- SLC24A2 | c.718C>T p.R240* | Nonsense Mutation (SNP) | VAF 46/214 reads (21%) | catalogued as COSV53878702; called by muse, mutect2, varscan2
- SORCS2 | c.958C>T p.R320W | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.814); catalogued as rs747884144, COSV61162520; called by muse, mutect2, varscan2
- SPAG16 | c.491A>C p.N164T | Missense Mutation (SNP) | VAF 86/245 reads (35%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.823); catalogued as COSV99793834; called by muse, mutect2, varscan2
- TYRP1 | c.795G>C p.L265F | Missense Mutation (SNP) | VAF 131/292 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.199); catalogued as COSV101141340; called by muse, mutect2, varscan2
- WDR17 | c.1854T>A p.N618K | Missense Mutation (SNP) | VAF 200/562 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99707770; called by muse, mutect2, varscan2
- ZNF681 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs150717337, COSV68073829; called by muse, mutect2, varscan2
- ZSCAN2 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs142869560; called by muse, mutect2, varscan2
- ARID1A | c.5789del p.S1930* | Frame Shift Del (DEL) | VAF 136/347 reads (39%) | called by mutect2, pindel, varscan2
- ITPR2 | c.2353dup p.M785Nfs*4 | Frame Shift Ins (INS) | VAF 91/301 reads (30%) | called by mutect2, pindel, varscan2
- NYNRIN | c.142_143del p.T48Pfs*77 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | called by pindel, varscan2
- RAB12 | c.517-3_517-2del p.X173_splice | Splice Site (DEL) | VAF 48/176 reads (27%) | called by mutect2, pindel, varscan2
- SDK1 | c.967_977del p.E323Cfs*46 | Frame Shift Del (DEL) | VAF 50/223 reads (22%) | called by mutect2, pindel, varscan2
- SMAD4 | c.410dup p.S138Ifs*5 | Frame Shift Ins (INS) | VAF 82/184 reads (45%) | called by mutect2, pindel, varscan2
- ANKAR | c.3384A>G p.E1128= | Silent (SNP) | VAF 89/262 reads (34%) | catalogued as COSV99854353; called by muse, mutect2, varscan2
- C2orf88 | c.168T>G p.T56= | Silent (SNP) | VAF 179/588 reads (30%) | catalogued as COSV100502735, COSV100502814; called by muse, mutect2, varscan2
- CREB3 | c.388T>C p.L130= | Silent (SNP) | VAF 53/167 reads (32%) | catalogued as rs766535577, COSV100147842; called by muse, mutect2, varscan2
- DSCAML1 | c.2007C>T p.I669= (on ENST00000321322; = p.I609= on NM_020693.4) | Silent (SNP) | VAF 39/177 reads (22%) | catalogued as rs140529836; called by muse, mutect2, varscan2
- EPHB2 | c.2937C>T p.N979= (on ENST00000400191 / NM_001309193.2; = p.N980= on NM_004442.7) | Silent (SNP) | VAF 55/131 reads (42%) | catalogued as COSV101007155; called by muse, mutect2, varscan2
- KCNQ5 | c.1143C>T p.Y381= | Silent (SNP) | VAF 15/233 reads (6%) | catalogued as rs144427126; called by muse, mutect2
- LRRC4 | c.1710G>A p.Q570= | Silent (SNP) | VAF 36/86 reads (42%) | catalogued as COSV99975041; called by muse, mutect2, varscan2
- MATN1 | c.640A>C p.R214= | Silent (SNP) | VAF 35/76 reads (46%) | catalogued as rs778726457, COSV101056343; called by muse, mutect2, varscan2
- MYF6 | c.129C>T p.P43= | Silent (SNP) | VAF 97/305 reads (32%) | catalogued as COSV99952859; called by muse, mutect2, varscan2
- NBPF26 | c.2478T>C p.G826= (on ENST00000620612; = p.G564= on NM_001351372.1) | Silent (SNP) | VAF 100/638 reads (16%) | called by muse, mutect2, varscan2
- PLCXD1 | c.936C>T p.D312= | Silent (SNP) | VAF 116/280 reads (41%) | catalogued as rs768067308, COSV100397782; called by muse, mutect2, varscan2
- PSME4 | c.5370A>G p.A1790= | Silent (SNP) | VAF 44/120 reads (37%) | catalogued as COSV101122536; called by muse, mutect2, varscan2
- PZP | c.4296G>A p.T1432= | Silent (SNP) | VAF 93/309 reads (30%) | catalogued as rs371639831, COSV54369432; called by muse, mutect2, varscan2
- RPSA | c.666G>A p.V222= | Silent (SNP) | VAF 22/203 reads (11%) | catalogued as COSV100088167; called by muse, varscan2
- SATB2 | c.948G>T p.L316= | Silent (SNP) | VAF 14/408 reads (3%) | catalogued as COSV99611489; called by muse, mutect2
- SLC36A2 | c.576G>A p.T192= | Silent (SNP) | VAF 93/312 reads (30%) | catalogued as rs774727485, COSV100079202; called by muse, mutect2, varscan2
- TLR3 | c.2457C>T p.H819= | Silent (SNP) | VAF 76/234 reads (32%) | catalogued as COSV57170734, COSV99711048; called by muse, mutect2, varscan2
- TLR5 | c.1044G>C p.L348= | Silent (SNP) | VAF 152/644 reads (24%) | catalogued as COSV100643302, COSV60558501; called by muse, mutect2, varscan2
- TRPM8 | c.2007C>T p.I669= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as rs201839664, COSV100224191; called by muse, mutect2, varscan2
- TXK | c.1524A>G p.E508= | Silent (SNP) | VAF 108/298 reads (36%) | catalogued as COSV99972511; called by muse, mutect2, varscan2
- UGGT2 | c.306C>T p.H102= | Silent (SNP) | VAF 141/446 reads (32%) | catalogued as COSV100942575; called by muse, mutect2, varscan2
- ZSCAN1 | c.165G>A p.A55= | Silent (SNP) | VAF 28/131 reads (21%) | catalogued as rs1333813805, COSV56603370; called by muse, mutect2
